Somatic mutation profile of tumor specimen MP2PRT-PATIKB-TMP1-A (aliquot MP2PRT-PATIKB-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATIKB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,012 days).
Specimen MP2PRT-PATIKB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb8f7c97-a812-4c7c-8ea2-fb689aced0cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATIKB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATIKB-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9273bd23-bbbb-4385-ab71-8e7012147f34

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Nonsense Mutation 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA2D3 | c.1870C>A p.H624N | Missense Mutation (SNP) | VAF 99/231 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV55589780; called by muse, mutect2, varscan2
- GNAS | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 79/510 reads (15%) | catalogued as rs374029864, COSV100005100; called by muse, mutect2, varscan2
- NBEAL1 | c.5320C>T p.R1774C | Missense Mutation (SNP) | VAF 134/345 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.328); catalogued as rs193094931; called by muse, mutect2, varscan2
- ADAMTS17 | c.873dup p.A292Rfs*2 | Frame Shift Ins (INS) | VAF 63/169 reads (37%) | called by mutect2, pindel*, varscan2*
- FEZF1 | c.930C>A p.H310Q | Missense Mutation (SNP) | VAF 10/336 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IGHV3-15 | c.337_338insGGTGGAACTGGGGATCCCCTCTCGCACAGTAATACACAG p.T112_A113insGWNWGSPLAQ* | Nonsense Mutation (INS) | VAF 6/40 reads (15%) | called by mutect2, pindel
- ZCCHC8 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 145/362 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MCM3AP | c.3021C>T p.S1007= | Silent (SNP) | VAF 107/223 reads (48%) | catalogued as rs758506839; called by muse, mutect2, varscan2
- TRDD3 | c.13G>A p.*5= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs367854479; called by muse, mutect2
